Somatic mutation profile of tumor specimen MP2PRT-PATUFY-TMP1-A (aliquot MP2PRT-PATUFY-TMP1-A-1-0-D-A81P-36) from MP2PRT case MP2PRT-PATUFY, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.6 years (946 days).
Specimen MP2PRT-PATUFY-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8c8dd21a-0e72-466a-8ddb-53e278535e71.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PATUFY-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PATUFY-NB1-A-1-0-D-A81P-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ea93a0c4-2ade-46db-bca7-2efa07e3a3cc

The open-access MAF lists 20 somatic variants for this specimen: 16 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, Silent 3, Splice Site 2, Nonsense Mutation 2, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EIF2AK4 | c.3766C>T p.R1256* | Nonsense Mutation (SNP) | VAF 15/86 reads (17%) | catalogued as rs587777207, CM1310868; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 77/392 reads (20%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen benign (0.323); catalogued as rs121434596, CM071907, COSV54736416, COSV54736480, COSV54736793; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADAMTS12 | c.1810C>T p.R604W | Missense Mutation (SNP) | VAF 22/302 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs371132100, COSV61261873; called by muse, mutect2
- CCDC39 | c.137G>A p.R46H | Missense Mutation (SNP) | VAF 21/190 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as rs376716008, COSV56486412; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CNTN6 | c.2207A>G p.Y736C | Missense Mutation (SNP) | VAF 56/215 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV63184934; called by muse, mutect2, varscan2
- CREBBP | c.4309A>T p.I1437F | Missense Mutation (SNP) | VAF 21/338 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.848); catalogued as COSV52112675; called by muse, mutect2
- DHCR24 | c.235C>T p.R79W | Missense Mutation (SNP) | VAF 42/196 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs780621933, COSV64875564; called by muse, mutect2, varscan2
- ERG | c.1109A>C p.D370A (on ENST00000398919 / NM_001243428.1; = p.D346A on NM_004449.4) | Missense Mutation (SNP) | VAF 47/813 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55729043; called by muse, mutect2
- F10 | c.535C>T p.R179C | Missense Mutation (SNP) | VAF 26/462 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as rs1277295882, CM014180, CM950369, COSV104429355; ClinVar: uncertain significance; called by muse, mutect2
- SEMG1 | c.1114C>T p.R372C | Missense Mutation (SNP) | VAF 50/271 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.012); catalogued as rs199672858, COSV54871705, COSV54872099; called by muse, mutect2, varscan2
- ARNT2 | c.1688T>C p.I563T | Missense Mutation (SNP) | VAF 64/354 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- C4orf54 | c.128G>C p.S43T | Missense Mutation (SNP) | VAF 32/542 reads (6%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.01); called by muse, mutect2
- CCNA2 | c.457+1G>A p.X153_splice | Splice Site (SNP) | VAF 30/197 reads (15%) | called by muse, mutect2, varscan2
- MOCS3 | c.543C>A p.D181E | Missense Mutation (SNP) | VAF 52/496 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SNRNP70 | c.212_213del p.X71_splice | Splice Site (DEL) | VAF 47/273 reads (17%) | called by pindel, varscan2
- TANC2 | c.886C>T p.R296* | Nonsense Mutation (SNP) | VAF 53/332 reads (16%) | called by muse, mutect2, varscan2
- GPR158 | c.1419C>T p.Y473= | Silent (SNP) | VAF 37/221 reads (17%) | called by muse, mutect2, varscan2
- IDS | c.585C>T p.T195= | Silent (SNP) | VAF 54/567 reads (10%) | called by muse, mutect2
- PHACTR2 | c.69A>T p.P23= | Silent (SNP) | VAF 110/980 reads (11%) | called by muse, mutect2
- AGAP1 | c.1051-30509G>A | Intron (SNP) | VAF 28/458 reads (6%) | catalogued as rs551312962; called by muse, mutect2
